Somatic mutation profile of tumor specimen C3N-00305-02 (aliquot CPT0011240009) from CPTAC case C3N-00305, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.1 years (21,957 days).
Specimen C3N-00305-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4b27370-7c9b-4179-b401-e88e72920389.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00305-31 (Blood Derived Normal), aliquot CPT0011270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a2c0a65-6076-4ad2-91dc-63b4c7662956

The open-access MAF lists 64 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 7, Nonsense Mutation 6, Frame Shift Del 5, 3'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARRB1 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.461); catalogued as COSV63575149; called by muse, mutect2, varscan2
- COMP | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 37/492 reads (8%) | catalogued as COSV55874857; called by muse, mutect2
- GABRG3 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV61512687; called by muse, mutect2, varscan2
- GGCX | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs139689026; called by muse, mutect2, varscan2
- KCNA4 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs372809586; called by muse, mutect2
- LAMP5 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55716920; called by muse, mutect2, varscan2
- MTR | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 60/389 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV63966462; called by muse, mutect2, varscan2
- PACS2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1555408209; called by muse, mutect2
- PBRM1 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV56301630; called by muse, mutect2
- PCDH15 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs146121822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLVAP | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53086432; called by mutect2, varscan2
- RALGAPB | c.3269C>A p.P1090H | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372998383; called by muse, mutect2, varscan2
- RBMXL1 | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 58/442 reads (13%) | catalogued as COSV99037172; called by muse, varscan2
- RP1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886062989, COSV55112474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SI | c.4964G>T p.R1655L | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as rs752540924, COSV100017187; called by muse, mutect2, varscan2
- VHL | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs869025659, CM023999, CS951541, COSV56543854, COSV56544010, COSV56545833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.1128A>C p.K376N | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL3 | c.84del p.K28Nfs*76 | Frame Shift Del (DEL) | VAF 31/185 reads (17%) | called by mutect2, pindel, varscan2
- ATAD3C | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATAD3C | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- C20orf203 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CAPN2 | c.912G>C p.W304C | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP152 | c.4526G>A p.R1509K (on ENST00000380950 / NM_001194998.2; = p.R1453K on NM_014985.4) | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DEK | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- DTNA | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GLRA2 | c.858G>C p.R286S | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GREB1 | c.3352_3362del p.K1118Vfs*54 | Frame Shift Del (DEL) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- MYO1B | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2A5 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- PCDH11X | c.2201C>G p.T734R | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- POSTN | c.66C>A p.N22K | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PPP2R3C | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RARB | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- SCAF1 | c.3643G>T p.E1215* | Nonsense Mutation (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- TRDN | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TSPAN19 | c.668del p.L223* | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- TTLL4 | c.2154G>T p.W718C | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- WDR81 | c.4293_4294del p.F1432Lfs*5 (on ENST00000409644 / NM_001163809.2; = p.F381Lfs*5 on NM_152348.4) | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by mutect2, pindel
- XPC | c.1978T>A p.Y660N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF544 | c.773del p.C258Ffs*9 | Frame Shift Del (DEL) | VAF 13/124 reads (10%) | called by mutect2, pindel, varscan2
- CACNA1F | c.3870T>A p.I1290= | Silent (SNP) | VAF 59/327 reads (18%) | called by muse, mutect2, varscan2
- CCIN | c.48G>A p.Q16= | Silent (SNP) | VAF 19/388 reads (5%) | catalogued as rs1267942130; called by muse, mutect2
- DISP2 | c.2221C>A p.R741= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs763603783; called by muse, mutect2, varscan2
- GOLGA6L2 | c.2664A>G p.G888= | Silent (SNP) | VAF 19/156 reads (12%) | called by muse, varscan2
- HEPACAM | c.1023C>A p.S341= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2
- HSFX3 | c.384C>A p.I128= | Silent (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- ICE2 | c.1593T>A p.T531= | Silent (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- IGLJ6 | c.6G>T p.G2= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as rs755956997; called by muse, mutect2, varscan2
- IL12A | c.198A>C p.P66= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- RAB37 | c.165G>A p.L55= | Silent (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- SNX29 | c.189G>A p.L63= | Silent (SNP) | VAF 34/235 reads (14%) | called by muse, mutect2, varscan2
- SOX17 | c.909C>T p.P303= | Silent (SNP) | VAF 20/125 reads (16%) | called by muse, varscan2
- SPATA31D1 | c.486G>A p.S162= | Silent (SNP) | VAF 83/428 reads (19%) | catalogued as rs575416308, COSV61194177; called by muse, mutect2, varscan2
- TSHR | c.333C>T p.T111= | Silent (SNP) | VAF 13/382 reads (3%) | called by muse, mutect2
- AC092718.9 | chr16:81156909 C>A | 3'Flank (SNP) | VAF 42/244 reads (17%) | catalogued as rs375813573; called by muse, mutect2, varscan2
- ADM2 | c.*19C>G | 3'UTR (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.265-103T>C | Intron (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- CGB7 | c.-2199G>A | 5'UTR (SNP) | VAF 28/212 reads (13%) | called by muse, mutect2, varscan2
- DDX17 | c.1447+1668C>T | Intron (SNP) | VAF 35/259 reads (14%) | called by muse, mutect2, varscan2
- EPS8L1 | c.1357-22C>T | Intron (SNP) | VAF 20/142 reads (14%) | catalogued as COSV52385842; called by muse, mutect2, varscan2
- FANCC | c.1329+156C>T | Intron (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+4085del | Intron (DEL) | VAF 20/159 reads (13%) | called by mutect2, pindel, varscan2
- MME | c.196+4743T>C | Intron (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- SMPD4 | c.1571-14C>T | Intron (SNP) | VAF 37/199 reads (19%) | called by muse, mutect2, varscan2
